Somatic mutation profile of tumor specimen TCGA-FG-7638-01B (aliquot TCGA-FG-7638-01B-11D-2086-08) from TCGA case TCGA-FG-7638, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 31.6 years (11,528 days).
Specimen TCGA-FG-7638-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 632c51a6-a6dd-47b2-89c8-ecc9966aca92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-7638-10A (Blood Derived Normal), aliquot TCGA-FG-7638-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f68a481-6192-4563-9041-b5019be0b27a

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 41/65 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568504941, COSV50547203; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 35/98 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANOS1 | c.1630C>A p.L544I | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99078797; called by muse, mutect2, varscan2
- KIR2DL1 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 12/339 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.132); catalogued as rs745719124; called by muse, mutect2
- LCE5A | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as rs752990455; called by muse, mutect2, varscan2
- NOTCH1 | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as CM159398, COSV53065420, COSV53102266; called by muse, mutect2
- UTS2R | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760796306; called by muse, mutect2
- ZPLD1 | c.677G>A p.G226D (on ENST00000466937 / NM_001329788.1; = p.G242D on NM_175056.2) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.076); catalogued as rs150699636, COSV60353322; called by muse, mutect2, varscan2
- ATRX | c.3391A>G p.R1131G | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH9 | c.2156C>A p.P719H | Missense Mutation (SNP) | VAF 86/213 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP11 | c.2312G>A p.G771E (on ENST00000218348; = p.G728E on NM_001371072.1) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ARMCX2 | c.33G>A p.A11= | Silent (SNP) | VAF 78/224 reads (35%) | catalogued as rs782784093; called by muse, mutect2, varscan2
- CIC | c.1233G>A p.A411= | Silent (SNP) | VAF 30/40 reads (75%) | catalogued as rs780429365, COSV50656766; called by muse, mutect2, varscan2
- GPRIN1 | c.78C>T p.A26= | Silent (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- ST6GALNAC4 | c.633C>G p.L211= | Silent (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- TMEM19 | c.483C>T p.V161= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as rs1239112695; called by muse, mutect2
- ZFAND5 | c.546C>T p.D182= | Silent (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23342G>A | Intron (SNP) | VAF 76/173 reads (44%) | catalogued as rs184388078; called by muse, mutect2, varscan2
